Somatic mutation profile of tumor specimen 0DRKKK from CCDI case PBCGEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Angiomatoid fibrous histiocytoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 14.2 years (5,173 days).
Specimen 0DRKKK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb929261-c5ea-4548-9dea-f289c403277d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71558c78-85ef-47a3-96d7-3e4733078d94

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 17/701 reads (2%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
